Somatic mutation profile of tumor specimen MMRF_2437_1_BM_CD138pos (aliquot MMRF_2437_1_BM_CD138pos_T1_KHS5U_L11601) from MMRF case MMRF_2437, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,139 days).
Specimen MMRF_2437_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f156be79-a0e4-4e72-a3cc-3c8d999f7d70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2437_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2437_1_PB_Whole_C3_KHS5U_L11602; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c00d2af-af90-46f2-9f4c-89e424820f29

The open-access MAF lists 122 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 31, Silent 14, Intron 7, 5'UTR 5, Splice Region 4, 3'Flank 4, Nonsense Mutation 4, RNA 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP32 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 166/565 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs761308907, COSV59848702; called by muse, mutect2, varscan2
- ARID1B | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51685468; called by muse, mutect2
- ARMC4 | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1025464178; called by muse, mutect2, varscan2
- ATP10A | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV63523286; called by muse, mutect2, varscan2
- CACNA1A | c.3448G>A p.V1150I | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as rs376365775, COSV64190950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD84 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs777494416, COSV60870954; called by muse, mutect2
- COPG1 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.412); catalogued as rs1043833633; called by muse, mutect2
- DCSTAMP | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs200192854, COSV52578874; called by muse, mutect2, varscan2
- DNAH9 | c.8367T>G p.N2789K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773081294; called by muse, mutect2, varscan2
- EFR3B | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1372610137; called by muse, mutect2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 96/104 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 112/121 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, mutect2, varscan2
- KANK3 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781649268; called by muse, mutect2, varscan2
- LGALS8 | c.345+5G>A | Splice Region (SNP) | VAF 19/178 reads (11%) | catalogued as rs1322589311; called by muse, mutect2, varscan2
- MORN4 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100167463; called by muse, mutect2
- RIPOR1 | c.3283C>T p.R1095* (on ENST00000379312 / NM_001193522.2; = p.R1091* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 10/132 reads (8%) | catalogued as rs1278640313, COSV50232017; called by muse, mutect2
- RYR2 | c.11087C>A p.A3696E | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1269339524; called by muse, mutect2, varscan2
- SHLD2 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as rs761643329; called by muse, mutect2
- SPEM2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 115/220 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV61604249; called by muse, mutect2, varscan2
- THNSL2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs761782074; called by muse, mutect2
- TNPO2 | c.2501dup p.V835Rfs*21 (on ENST00000425528 / NM_001382240.1; = p.V825Rfs*21 on NM_013433.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 31/95 reads (33%) | catalogued as rs776213759; called by mutect2, pindel, varscan2
- TRPM7 | c.2355C>G p.I785M | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.897); catalogued as COSV57915719; called by muse, mutect2
- TTN | c.46537G>A p.V15513I (on ENST00000591111; = p.V8089I on NM_003319.4) | Missense Mutation (SNP) | VAF 69/153 reads (45%) | PolyPhen benign (0.117); catalogued as rs374701373; called by muse, mutect2
- ZBTB33 | c.798A>T p.K266N | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100434013; called by muse, mutect2
- ZNF229 | c.1190G>T p.R397M | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52164779; called by muse, mutect2, varscan2
- ZNF467 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs1231632372, COSV100118162, COSV57373322; called by muse, mutect2, varscan2
- ADAMTS14 | c.3040C>T p.Q1014* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- ANK1 | c.5089C>T p.Q1697* | Nonsense Mutation (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- CAPN6 | c.1097C>G p.P366R | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- CDK5RAP3 | c.51C>T p.L17= | Splice Region (SNP) | VAF 117/221 reads (53%) | called by muse, mutect2, varscan2
- DMXL2 | c.7130A>G p.N2377S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2
- DNAJC6 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EHBP1L1 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- ESYT3 | c.369G>A p.K123= | Splice Region (SNP) | VAF 68/228 reads (30%) | called by muse, mutect2
- GRK3 | c.1050T>C p.S350= | Splice Region (SNP) | VAF 91/101 reads (90%) | called by muse, mutect2, varscan2
- KRTAP13-3 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- LYPD1 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.753); called by muse, mutect2
- MAP3K7 | c.1080+1G>T p.X360_splice | Splice Site (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- MED28 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MRGPRX4 | c.62C>G p.T21S | Missense Mutation (SNP) | VAF 29/419 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.027); called by muse, mutect2
- NAGK | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- NPC1L1 | c.3689A>C p.E1230A | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- POLG2 | c.833_834dup p.Q279Vfs*22 | Frame Shift Ins (INS) | VAF 108/298 reads (36%) | called by mutect2, pindel, varscan2
- PPP2R1B | c.1745A>T p.D582V | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKD1 | c.930A>C p.K310N | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRKD2 | c.1652T>A p.I551N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRC | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- RHOBTB2 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCLT1 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPATA16 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM64C | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRIO | c.2946G>A p.M982I | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TSHZ3 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 50/702 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- TSSK6 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR31 | c.287T>C p.V96A (on ENST00000374193 / NM_001006615.3; = p.V95A on NM_145241.5) | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.185); called by muse, mutect2
- ZDHHC5 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZNF263 | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF462 | c.5155C>A p.R1719S | Missense Mutation (SNP) | VAF 44/467 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF837 | c.16_23del p.Q6Wfs*49 | Frame Shift Del (DEL) | VAF 51/132 reads (39%) | called by mutect2, pindel, varscan2
- ARHGEF4 | c.1578C>T p.H526= | Silent (SNP) | VAF 11/179 reads (6%) | catalogued as COSV58125245; called by muse, mutect2
- CACNG7 | c.780C>T p.P260= | Silent (SNP) | VAF 246/593 reads (41%) | called by muse, mutect2, varscan2
- CBX1 | c.378A>G p.T126= | Silent (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- GJA8 | c.648C>T p.S216= | Silent (SNP) | VAF 120/243 reads (49%) | called by muse, mutect2, varscan2
- MEGF6 | c.1278C>T p.H426= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- MYH1 | c.2751C>T p.I917= | Silent (SNP) | VAF 22/300 reads (7%) | catalogued as COSV99875208; called by muse, mutect2
- MYH15 | c.1522C>T p.L508= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- NKX3-2 | c.768C>T p.N256= | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- NR5A2 | c.843C>T p.P281= (on ENST00000367362 / NM_205860.3; = p.P235= on NM_003822.5) | Silent (SNP) | VAF 97/226 reads (43%) | catalogued as rs776091744; called by muse, mutect2, varscan2
- NXPE2 | c.840C>T p.S280= | Silent (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- OR4K1 | c.357A>G p.A119= | Silent (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- POGK | c.1479G>A p.V493= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- TEX45 | c.492G>A p.K164= | Silent (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- TXNDC5 | c.372C>T p.H124= | Silent (SNP) | VAF 234/423 reads (55%) | called by muse, mutect2, varscan2
- AGFG2 | c.*3192G>A | 3'UTR (SNP) | VAF 7/71 reads (10%) | catalogued as rs1031927013; called by muse, mutect2
- B4GAT1 | c.-66G>A | 5'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- C5orf67 | n.467G>A | RNA (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949768 A>C | 3'Flank (SNP) | VAF 58/133 reads (44%) | called by muse, mutect2, varscan2
- CACNG8 | c.*6939G>C | 3'UTR (SNP) | VAF 14/265 reads (5%) | called by muse, mutect2
- CCDC68 | chr18:54901911 A>C | 3'Flank (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- CD300E | c.*1718C>T | 3'UTR (SNP) | VAF 138/283 reads (49%) | called by muse, mutect2, varscan2
- CDK1 | c.*106C>T | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- CHP1 | c.*2299A>T | 3'UTR (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- CREB5 | c.*3987T>A | 3'UTR (SNP) | VAF 57/102 reads (56%) | called by muse, mutect2, varscan2
- DNMT1 | c.3476-25C>T | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- FAM177A1 | c.96+77C>T | Intron (SNP) | VAF 84/188 reads (45%) | catalogued as rs1489571323; called by muse, mutect2
- FBXL17 | c.1965+2743A>T | Intron (SNP) | VAF 40/115 reads (35%) | called by muse, mutect2, varscan2
- GAS2 | chr11:22813011 A>T | 3'Flank (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- GIMAP1 | c.*1961A>G | 3'UTR (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- GRK4 | c.52+2280A>T | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- GYPA | c.*664T>C | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2, varscan2
- HFE | c.*3273G>C | 3'UTR (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- KDM6A | c.162-90C>T | Intron (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- MAN1A2 | c.*5034G>C | 3'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- MARK4 | c.-38C>A | 5'UTR (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- MOSPD2 | c.*982A>C | 3'UTR (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- NFIB | c.*1700C>T | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- NKX6-3 | c.*1078T>C | 3'UTR (SNP) | VAF 58/91 reads (64%) | called by muse, mutect2, varscan2
- NOX4 | c.447+34C>A | Intron (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87874221 A>C | 3'Flank (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- OARD1 | c.*1490T>A | 3'UTR (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- OPN5 | c.*6G>T | 3'UTR (SNP) | VAF 258/539 reads (48%) | called by muse, mutect2, varscan2
- PITPNB | c.20+59G>T | Intron (SNP) | VAF 16/314 reads (5%) | catalogued as COSV100086955; called by muse, mutect2
- PLS1 | c.*1097G>C | 3'UTR (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- POLE4 | c.*672C>T | 3'UTR (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- PPP1R13B | c.*660C>T | 3'UTR (SNP) | VAF 14/95 reads (15%) | catalogued as rs1186055343; called by muse, mutect2, varscan2
- PRKD1 | c.*533C>T | 3'UTR (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- RGS6 | c.*39C>A | 3'UTR (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- RPL37A | c.*1474G>A | 3'UTR (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- RPS6KA1 | c.*64G>A | 3'UTR (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- RUFY3 | c.*1200T>C | 3'UTR (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- SLC26A7 | c.-60del | 5'UTR (DEL) | VAF 122/505 reads (24%) | catalogued as COSV52590451; called by pindel, varscan2
- SNORD116-17 | n.31C>T | RNA (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- STMN1 | c.*249T>C | 3'UTR (SNP) | VAF 77/141 reads (55%) | catalogued as rs1437138384; called by muse, mutect2, varscan2
- TP53RK | c.-3G>T | 5'UTR (SNP) | VAF 13/246 reads (5%) | called by muse, mutect2
- TRMT9B | c.*1738G>A | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- UBE2W | c.*7721C>A | 3'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- VAMP4 | c.*1420G>T | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- WDFY4 | c.*159C>A | 3'UTR (SNP) | VAF 40/456 reads (9%) | called by muse, mutect2
- WIPF2 | c.*904G>T | 3'UTR (SNP) | VAF 19/202 reads (9%) | called by muse, mutect2
- ZC3HAV1 | c.*31A>T | 3'UTR (SNP) | VAF 21/464 reads (5%) | called by muse, mutect2
- ZFPM2 | c.-202C>T | 5'UTR (SNP) | VAF 130/339 reads (38%) | called by muse, mutect2, varscan2
- ZNF516 | c.*3586G>C | 3'UTR (SNP) | VAF 160/407 reads (39%) | called by muse, mutect2
